Somatic mutation profile of tumor specimen HCM-CSHL-0510-D13-86A (aliquot HCM-CSHL-0510-D13-86A-01D-A85C-36) from HCMI case HCM-CSHL-0510-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 59.1 years (21,570 days).
Specimen HCM-CSHL-0510-D13-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88abd52e-5361-4963-b10f-241e48f88690.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0510-D13-10A (Blood Derived Normal), aliquot HCM-CSHL-0510-D13-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/091d7816-20b0-404f-83ae-21a6be32bfa1

The open-access MAF lists 194 somatic variants for this specimen: 136 protein-altering or splice-affecting, 53 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 53, Frame Shift Ins 4, Nonsense Mutation 3, Intron 2, Splice Site 2, 3'Flank 1, Frame Shift Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 227/367 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACMSD | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV99298755; called by muse, mutect2, varscan2
- ADGRA1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 297/586 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs779122897, COSV66926538; called by muse, mutect2, varscan2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 185/190 reads (97%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- ARHGAP17 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 114/211 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs746155178; called by muse, mutect2, varscan2
- ATP1B2 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs937145780, COSV100006883; called by muse, mutect2, varscan2
- AXL | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 223/456 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs138219571; called by muse, mutect2, varscan2
- BRINP1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 171/374 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs987725274, COSV56293277; called by muse, mutect2, varscan2
- BRWD3 | c.2888C>A p.S963* | Nonsense Mutation (SNP) | VAF 122/249 reads (49%) | catalogued as COSV64751280; called by muse, mutect2, varscan2
- C10orf71 | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60514516; called by muse, mutect2, varscan2
- CAMTA1 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 259/484 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.105); catalogued as rs576226270, COSV57903148, COSV57916355; called by muse, mutect2, varscan2
- CATSPER4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 198/362 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781301429; called by muse, mutect2, varscan2
- CCDC168 | c.13968G>T p.E4656D | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as rs930520789, COSV100487810; called by muse, mutect2, varscan2
- CD2AP | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs779860972; called by muse, mutect2, varscan2
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 176/395 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, mutect2, varscan2
- CERKL | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as rs1180928247, COSV59208345; called by muse, mutect2, varscan2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 246/470 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, mutect2, varscan2
- CFAP47 | c.7418G>A p.R2473H | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1388166915; called by muse, mutect2, varscan2
- CLCA4 | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs553556484, COSV100991174; called by muse, mutect2, varscan2
- CNTN4 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 206/339 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.63); catalogued as rs371362562, COSV100639240; called by muse, mutect2, varscan2
- CNTNAP2 | c.1520A>T p.N507I | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV62154563, COSV62237131; called by muse, mutect2, varscan2
- CSNKA2IP | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 185/379 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1014219433; called by muse, mutect2, varscan2
- CTDP1 | c.2045C>T p.T682M | Missense Mutation (SNP) | VAF 228/536 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867198820; called by muse, mutect2, varscan2
- CWC22 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844131; called by muse, mutect2
- CXorf56 | c.397C>T p.R133W (on ENST00000536133 / NM_001170570.2; = p.R147W on NM_022101.4) | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57438357; called by muse, mutect2, varscan2
- DHTKD1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 250/472 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs756540722, COSV53802706, COSV99536414; called by muse, varscan2
- DSPP | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs756720862; called by muse, mutect2
- EPHB1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 202/427 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs373293977; called by muse, mutect2, varscan2
- F2R | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 223/443 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs777334197, COSV59930250; called by muse, mutect2, varscan2
- FAM90A1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.857); catalogued as rs373760588; called by muse, mutect2, varscan2
- FAT4 | c.11161G>A p.V3721I | Missense Mutation (SNP) | VAF 126/483 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as rs557732280, COSV58675364; called by muse, mutect2, varscan2
- FRMD6 | c.569A>G p.K190R (on ENST00000344768 / NM_001267046.2; = p.K182R on NM_152330.4) | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1459440409, COSV61088683; called by muse, mutect2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- GDF1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 262/496 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs1438878646; called by muse, mutect2, varscan2
- GPR150 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 275/508 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as rs1442232469, COSV66168046; called by muse, mutect2, varscan2
- GTPBP1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 265/530 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1307294473; called by muse, mutect2, varscan2
- HLA-C | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 295/711 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs75512631; called by muse, mutect2
- HRAS | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 335/654 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54240340; called by muse, mutect2, varscan2
- HTRA3 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 170/311 reads (55%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1017083985; called by muse, mutect2, varscan2
- INSL6 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 148/296 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767494322, COSV67562518; called by muse, mutect2, varscan2
- ITFG2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1005215879, COSV99958270; called by muse, mutect2, varscan2
- JRK | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 137/771 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs192430225, COSV70629834; called by muse, mutect2, varscan2
- KLHL34 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 58/700 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.46); catalogued as rs1350335319, COSV65279503; called by muse, mutect2
- KMT2B | c.7715C>T p.T2572M | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs867499379, COSV53074231; called by muse, mutect2, varscan2
- LLCFC1 | c.332C>T p.T111M (on ENST00000458732; = p.T80M on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 248/528 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs369000744, COSV100787015; called by muse, varscan2
- LRP1B | c.2924G>T p.C975F | Missense Mutation (SNP) | VAF 155/314 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67187329; called by muse, mutect2, varscan2
- MTNR1B | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 285/583 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1345298351, COSV57066059; called by muse, mutect2, varscan2
- NCAM1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 98/225 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs782485722; called by muse, mutect2, varscan2
- NCOA3 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59064962; called by muse, mutect2, varscan2
- NRXN3 | c.881G>A p.R294H (on ENST00000557594 / NM_001272020.2; = p.R926H on NM_004796.6) | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs144373051; called by muse, mutect2, varscan2
- NWD2 | c.3310G>A p.V1104I | Missense Mutation (SNP) | VAF 194/386 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs775787015, COSV58754013; called by muse, mutect2, varscan2
- OR2M7 | c.796C>A p.H266N | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV58740004; called by muse, mutect2, varscan2
- OR4C15 | c.641T>A p.L214H (on ENST00000314644; = p.L160H on NM_001001920.2) | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV58952960; called by muse, mutect2, varscan2
- PATE1 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV59825423, COSV99986280; called by muse, mutect2, varscan2
- PCDH15 | c.4707G>T p.K1569N | Missense Mutation (SNP) | VAF 206/428 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57258622; called by muse, mutect2, varscan2
- PCDH8 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 148/774 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs752290702; called by muse, mutect2
- PCDHB9 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 240/472 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782422350; called by muse, mutect2, varscan2
- PCDHGB2 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 135/433 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs757587046, COSV53894173; called by muse, mutect2, varscan2
- RHOXF2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 179/854 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs782250177; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/556 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- RPL3L | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs530918397, COSV51905287; called by muse, mutect2, varscan2
- SCN10A | c.5483A>C p.K1828T | Missense Mutation (SNP) | VAF 81/485 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561114332, COSV71860342, COSV71862308; called by muse, mutect2, varscan2
- SEPSECS | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 71/384 reads (18%) | catalogued as rs773969315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs781963874, COSV53206387; called by muse, mutect2, varscan2
- SOX17 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 351/1120 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV52024544, COSV52025261; called by muse, mutect2, varscan2
- SPATA31A7 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 108/513 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.134); catalogued as rs200244273; called by muse, mutect2, varscan2
- TANC2 | c.4684G>A p.V1562M | Missense Mutation (SNP) | VAF 191/384 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.495); catalogued as rs368956259, COSV67331062; called by muse, mutect2, varscan2
- TCHHL1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 170/377 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1342896445; called by muse, mutect2, varscan2
- TFCP2L1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558729042; called by muse, mutect2, varscan2
- THOC2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 204/416 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs761579225; called by muse, mutect2, varscan2
- TMEM259 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 310/660 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs201156482, COSV52261519; called by muse, mutect2
- TNIP1 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs548565909, COSV100161002, COSV100161705; called by muse, mutect2, varscan2
- TTN | c.9083G>T p.R3028M (on ENST00000591111; = p.R2982M on NM_003319.4) | Missense Mutation (SNP) | VAF 124/454 reads (27%) | PolyPhen probably damaging (0.998); catalogued as COSV60353046; called by muse, mutect2, varscan2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 178/516 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- TXNDC12 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 131/303 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217242438; called by muse, mutect2, varscan2
- ULK2 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs372735795; called by muse, mutect2, varscan2
- XRRA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs769038963; called by muse, mutect2, varscan2
- ZFP92 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 365/790 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1556975120, COSV58598291; called by muse, mutect2, varscan2
- ZIM2 | c.1062A>T p.K354N | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV55624447, COSV99687178; called by muse, mutect2, varscan2
- ZIM3 | c.1201T>C p.F401L | Missense Mutation (SNP) | VAF 76/308 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54146450; called by muse, mutect2, varscan2
- ZNF804B | c.2537G>T p.C846F | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.38); catalogued as COSV60814748; called by muse, mutect2, varscan2
- ABHD17B | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS7 | c.3746C>T p.T1249I | Missense Mutation (SNP) | VAF 49/500 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- APOB | c.5986T>A p.L1996M | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ARHGAP6 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 329/679 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CARMIL3 | c.2155dup p.R719Pfs*19 | Frame Shift Ins (INS) | VAF 114/302 reads (38%) | called by mutect2, pindel, varscan2
- CELSR1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 148/470 reads (31%) | called by muse, mutect2, varscan2
- CERKL | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 208/415 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- CH25H | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 221/399 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COPS5 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 173/279 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CYLC1 | c.778A>C p.N260H | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFR3A | c.368T>G p.F123C | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB2 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 453/679 reads (67%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ETNPPL | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 196/442 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EYS | c.2966A>C p.N989T | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FADD | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 41/568 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); called by muse, mutect2
- FAT3 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GFRAL | c.37T>A p.L13M | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GRXCR1 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPA5 | c.217dup p.E73Gfs*22 | Frame Shift Ins (INS) | VAF 118/489 reads (24%) | called by mutect2, pindel, varscan2
- ITGAM | c.154dup p.Q52Pfs*64 | Frame Shift Ins (INS) | VAF 89/307 reads (29%) | called by mutect2, pindel, varscan2
- ITPR1 | c.1483C>A p.L495I (on ENST00000354582; = p.L480I on NM_002222.7) | Missense Mutation (SNP) | VAF 67/399 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA0319L | c.2996G>A p.S999N | Missense Mutation (SNP) | VAF 142/297 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, varscan2
- LINC02218 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 138/343 reads (40%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LPL | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAPK3 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 199/455 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MBD3L5 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- NKAIN2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 207/465 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- NOX4 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRAP | c.3223C>A p.Q1075K (on ENST00000359988 / NM_001322945.2; = p.Q1040K on NM_006175.4) | Missense Mutation (SNP) | VAF 154/287 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR11H7 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2
- OR5T1 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR8H1 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 167/329 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PCF11 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCF11 | c.3581A>C p.N1194T | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R16A | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 234/671 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- PPP4R3C | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 139/311 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RHOBTB3 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by mutect2, varscan2
- ROBO2 | c.4108A>T p.S1370C | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RPS6KA1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RXFP1 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 193/394 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD2 | c.7429G>A p.E2477K | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- SLC35A5 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX1 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 290/571 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- STRAP | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 109/202 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SYNE3 | c.2727+1G>C p.X909_splice | Splice Site (SNP) | VAF 72/366 reads (20%) | called by muse, mutect2, varscan2
- TAF11L13 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TENM1 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMCO4 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 177/352 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.2261_2262insGG p.S754Rfs*21 | Frame Shift Ins (INS) | VAF 124/270 reads (46%) | called by mutect2, varscan2
- TPRG1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TTN | c.63143A>T p.N21048I (on ENST00000591111; = p.N13624I on NM_003319.4) | Missense Mutation (SNP) | VAF 44/286 reads (15%) | PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- USP32 | c.2022+1G>T p.X674_splice | Splice Site (SNP) | VAF 45/176 reads (26%) | called by muse, mutect2, varscan2
- VPS13B | c.8853G>T p.K2951N | Missense Mutation (SNP) | VAF 112/337 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF324 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 107/467 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC12 | c.759G>A p.A253= | Silent (SNP) | VAF 87/482 reads (18%) | catalogued as rs778359631, COSV60912543; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.432G>A p.S144= | Silent (SNP) | VAF 208/411 reads (51%) | catalogued as rs139118990; called by muse, mutect2, varscan2
- ADAMTS19 | c.2461A>C p.R821= | Silent (SNP) | VAF 67/263 reads (25%) | catalogued as COSV99177320; called by muse, mutect2, varscan2
- ADGRB1 | c.3942G>A p.A1314= | Silent (SNP) | VAF 108/782 reads (14%) | catalogued as rs746758009; called by muse, mutect2, varscan2
- ANKRD24 | c.2931C>T p.N977= | Silent (SNP) | VAF 283/610 reads (46%) | catalogued as rs1019103263; called by muse, mutect2, varscan2
- APBA1 | c.273C>T p.T91= | Silent (SNP) | VAF 125/739 reads (17%) | catalogued as rs1389676254; called by muse, mutect2, varscan2
- BCL11A | c.1974G>A p.S658= (on ENST00000335712 / NM_001365609.1; = p.S692= on NM_018014.4) | Silent (SNP) | VAF 289/563 reads (51%) | catalogued as rs146556401; called by muse, mutect2, varscan2
- BTNL9 | c.633G>T p.L211= | Silent (SNP) | VAF 96/419 reads (23%) | called by muse, mutect2, varscan2
- C4orf54 | c.4998C>T p.A1666= | Silent (SNP) | VAF 148/306 reads (48%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.2133C>T p.T711= | Silent (SNP) | VAF 248/469 reads (53%) | catalogued as rs186741880, COSV100409995; called by muse, mutect2, varscan2
- CD163L1 | c.2361G>A p.L787= | Silent (SNP) | VAF 100/208 reads (48%) | called by muse, mutect2, varscan2
- CHD7 | c.7086C>T p.S2362= | Silent (SNP) | VAF 157/541 reads (29%) | catalogued as rs757280832; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CPQ | c.468C>T p.F156= | Silent (SNP) | VAF 150/445 reads (34%) | catalogued as rs1237209399, COSV55162497; called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>T p.A161= | Silent (SNP) | VAF 205/600 reads (34%) | catalogued as COSV60480151; called by muse, mutect2, varscan2
- DNAH5 | c.8716C>T p.L2906= | Silent (SNP) | VAF 177/402 reads (44%) | catalogued as COSV54210372; called by muse, mutect2, varscan2
- EPN2 | c.1140A>G p.P380= | Silent (SNP) | VAF 196/391 reads (50%) | catalogued as rs768002641; called by muse, mutect2, varscan2
- FOXD4L4 | c.240G>A p.P80= | Silent (SNP) | VAF 94/1274 reads (7%) | called by muse, mutect2
- FRMD6 | c.567C>T p.S189= (on ENST00000344768 / NM_001267046.2; = p.S181= on NM_152330.4) | Silent (SNP) | VAF 52/224 reads (23%) | called by muse, mutect2
- GPR15 | c.963G>A p.L321= | Silent (SNP) | VAF 160/330 reads (48%) | called by muse, mutect2, varscan2
- GSTM4 | c.222C>T p.N74= | Silent (SNP) | VAF 202/502 reads (40%) | catalogued as rs375225696; called by muse, mutect2, varscan2
- H2AC4 | c.126G>A p.E42= | Silent (SNP) | VAF 49/345 reads (14%) | catalogued as COSV52519191; called by muse, mutect2, varscan2
- HERC2 | c.13449C>T p.S4483= | Silent (SNP) | VAF 233/451 reads (52%) | catalogued as rs764614115; called by muse, mutect2, varscan2
- HM13 | c.900C>T p.F300= | Silent (SNP) | VAF 48/359 reads (13%) | catalogued as rs145295632; called by muse, mutect2, varscan2
- HOXB8 | c.291C>T p.F97= | Silent (SNP) | VAF 278/582 reads (48%) | called by muse, varscan2
- IGHV2-26 | c.165G>A p.V55= | Silent (SNP) | VAF 166/1097 reads (15%) | catalogued as rs1237847762; called by muse, mutect2, varscan2
- KCNB1 | c.165G>A p.T55= | Silent (SNP) | VAF 119/626 reads (19%) | catalogued as rs1283291171; called by muse, mutect2, varscan2
- MAGEE2 | c.219C>T p.D73= | Silent (SNP) | VAF 138/547 reads (25%) | catalogued as rs749734220, COSV64898399; called by muse, mutect2, varscan2
- MAP3K5 | c.3135G>A p.R1045= | Silent (SNP) | VAF 196/401 reads (49%) | called by muse, mutect2, varscan2
- MC3R | c.684C>T p.D228= | Silent (SNP) | VAF 271/517 reads (52%) | catalogued as COSV54765274; called by muse, mutect2, varscan2
- MYH7 | c.4641C>T p.A1547= | Silent (SNP) | VAF 145/239 reads (61%) | catalogued as rs376854724; called by muse, mutect2, varscan2
- NKX1-1 | c.1083C>T p.S361= | Silent (SNP) | VAF 254/480 reads (53%) | called by muse, mutect2, varscan2
- NSG1 | c.222G>A p.T74= | Silent (SNP) | VAF 190/416 reads (46%) | catalogued as rs779838685; called by muse, mutect2, varscan2
- OR8B8 | c.297T>C p.T99= | Silent (SNP) | VAF 90/411 reads (22%) | called by muse, mutect2, varscan2
- PDE3A | c.99G>A p.A33= | Silent (SNP) | VAF 282/586 reads (48%) | called by muse, varscan2
- PGR | c.873C>T p.P291= | Silent (SNP) | VAF 347/751 reads (46%) | catalogued as COSV54795552; called by muse, mutect2, varscan2
- PHLDA2 | c.225C>A p.T75= | Silent (SNP) | VAF 145/675 reads (21%) | called by muse, mutect2, varscan2
- PIK3CG | c.1026C>T p.H342= | Silent (SNP) | VAF 164/356 reads (46%) | catalogued as rs539823993, COSV63253458; called by muse, mutect2, varscan2
- PRAMEF19 | c.999C>T p.R333= | Silent (SNP) | VAF 92/444 reads (21%) | catalogued as rs747673583; called by muse, varscan2
- SALL2 | c.1554A>G p.E518= | Silent (SNP) | VAF 195/417 reads (47%) | called by muse, mutect2, varscan2
- SLC35D3 | c.579C>T p.I193= | Silent (SNP) | VAF 317/640 reads (50%) | catalogued as rs201285388; called by muse, mutect2, varscan2
- SLC4A1 | c.489C>T p.H163= | Silent (SNP) | VAF 71/250 reads (28%) | catalogued as rs149933181; called by muse, mutect2, varscan2
- SLC8A1 | c.1515A>C p.S505= | Silent (SNP) | VAF 93/367 reads (25%) | called by muse, mutect2, varscan2
- SOX17 | c.567C>T p.P189= | Silent (SNP) | VAF 166/1289 reads (13%) | catalogued as rs780594698; called by muse, mutect2, varscan2
- SSTR3 | c.879G>C p.G293= | Silent (SNP) | VAF 86/481 reads (18%) | called by muse, mutect2, varscan2
- TBC1D12 | c.1137T>C p.P379= | Silent (SNP) | VAF 74/396 reads (19%) | called by muse, mutect2, varscan2
- TERB2 | c.30C>T p.C10= | Silent (SNP) | VAF 56/250 reads (22%) | catalogued as rs776218878; called by muse, varscan2
- TGFBR2 | c.1659G>A p.S553= | Silent (SNP) | VAF 85/428 reads (20%) | catalogued as rs771926828, COSV55453283; called by muse, mutect2, varscan2
- TIAM1 | c.4521C>T p.D1507= | Silent (SNP) | VAF 202/408 reads (50%) | catalogued as rs1228855775; called by muse, mutect2, varscan2
- TMEM151A | c.246C>T p.A82= | Silent (SNP) | VAF 212/743 reads (29%) | catalogued as rs765645259; called by muse, mutect2, varscan2
- TMEM271 | c.141C>T p.A47= | Silent (SNP) | VAF 313/641 reads (49%) | called by muse, mutect2, varscan2
- TSPAN32 | c.864G>A p.A288= | Silent (SNP) | VAF 144/425 reads (34%) | catalogued as rs977815677, COSV99478487; called by muse, mutect2, varscan2
- ZFPM2 | c.1398T>C p.S466= | Silent (SNP) | VAF 102/579 reads (18%) | catalogued as COSV101023236, COSV65872815, COSV65874990; called by muse, mutect2, varscan2
- ZFPM2 | c.2505G>A p.K835= | Silent (SNP) | VAF 188/584 reads (32%) | catalogued as COSV65874820; called by muse, mutect2, varscan2
- DISP1 | c.-176+21880C>T | Intron (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- GABARAPL1 | c.288+119C>T | Intron (SNP) | VAF 193/377 reads (51%) | catalogued as rs1259130198; called by muse, mutect2, varscan2
- LINC00662 | n.687C>T | RNA (SNP) | VAF 146/309 reads (47%) | catalogued as rs768383838; called by muse, mutect2, varscan2
- MYL3 | chr3:46833947 G>A | 3'Flank (SNP) | VAF 537/842 reads (64%) | catalogued as rs868399479; called by muse, mutect2, varscan2
- TBXA2R | c.*24G>A | 3'UTR (SNP) | VAF 328/636 reads (52%) | catalogued as rs200736764; called by muse, mutect2, varscan2
